Somatic mutation profile of tumor specimen BLGSP-71-06-00292-01A (aliquot BLGSP-71-06-00292-01A-01D-A690-33) from CGCI case BLGSP-71-06-00292, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.6 years (2,409 days).
Specimen BLGSP-71-06-00292-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da60ec72-ad15-46d1-8d66-baa269ef9458.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00292-12A (Buccal Cell Normal), aliquot BLGSP-71-06-00292-12A-01W-A690-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25f31d29-5392-4624-81e9-d6bac1caddc5

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 2, In Frame Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SIN3A | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 131/272 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV64582343; called by muse, mutect2, varscan2
- DOCK4 | c.2443A>C p.T815P | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PHF6 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SRSF7 | c.318C>G p.C106W | Missense Mutation (SNP) | VAF 219/508 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBL1XR1 | c.1182_1190del p.Y395_I397del | In Frame Del (DEL) | VAF 30/281 reads (11%) | called by mutect2, pindel
- DCHS2 | n.3046C>T | RNA (SNP) | VAF 212/478 reads (44%) | catalogued as rs774677154, COSV59717808; called by muse, varscan2
- DST | c.4297-2122C>A | Intron (SNP) | VAF 273/643 reads (42%) | called by muse, mutect2, varscan2
- MYC | c.-291G>A | 5'UTR (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- MYC | c.-60G>A | 5'UTR (SNP) | VAF 72/149 reads (48%) | called by muse, mutect2, varscan2
